Somatic mutation profile of tumor specimen TCGA-14-0812-01B (aliquot TCGA-14-0812-01B-01W-0643-08) from TCGA case TCGA-14-0812, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-14-0812-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56f490bd-1cfd-4bdb-a96d-58063627ff22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0812-10A (Blood Derived Normal), aliquot TCGA-14-0812-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f53f587f-42f0-4d8b-8a4e-05247ca98f43

The open-access MAF lists 54 somatic variants for this specimen: 46 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, In Frame Del 2, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1960+1G>A p.X654_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); catalogued as CD941779, CS071258, CS143247, COSV57306404, COSV57326412, COSV57330877; called by muse, mutect2, varscan2
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 137/250 reads (55%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- AADACL3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs775970102, COSV100206865, COSV60200385; called by muse, mutect2, varscan2
- ABCC8 | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100217673; called by muse, mutect2, varscan2
- ATP12A | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99518372; called by muse, mutect2
- C18orf54 | c.292A>T p.N98Y | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100266691; called by muse, mutect2, varscan2
- C2orf16 | c.4057C>A p.L1353I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100820976; called by muse, mutect2
- CCDC178 | c.2480A>T p.Q827L (on ENST00000383096 / NM_001105528.3; = p.Q789L on NM_198995.3) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.723); catalogued as COSV100286469; called by muse, mutect2, varscan2
- CCL20 | c.98G>C p.C33S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721885; called by muse, mutect2, varscan2
- CHD5 | c.5290C>T p.R1764W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752217521, COSV99314840; called by muse, varscan2
- EGLN2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 152/511 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349997342, COSV58279843; called by muse, mutect2, varscan2
- HCN1 | c.2144G>C p.R715P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as rs1242068538, COSV100302034, COSV57497988; called by mutect2, varscan2
- KIF21A | c.3728G>T p.R1243M (on ENST00000361418 / NM_001378440.1; = p.R1230M on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV100735619; called by muse, mutect2, varscan2
- KLK4 | c.474C>T p.N158= | Splice Region (SNP) | VAF 41/148 reads (28%) | catalogued as rs745811664, COSV60676094; called by muse, mutect2, varscan2
- KRT12 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs971553130, COSV99289110; called by muse, mutect2, varscan2
- KRT31 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 174/412 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs141715467; called by muse, mutect2, varscan2
- MFSD6L | c.1581C>A p.C527* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100319876; called by muse, mutect2, varscan2
- MICALL1 | c.2539C>A p.L847M | Missense Mutation (SNP) | VAF 59/594 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV99317530; called by muse, mutect2, varscan2
- NLRP13 | c.1156T>C p.F386L | Missense Mutation (SNP) | VAF 8/249 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100738476; called by muse, mutect2
- NME8 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV52250387; called by muse, mutect2, varscan2
- NPY5R | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100642911; called by muse, mutect2, varscan2
- NR2F2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101241160; called by muse, mutect2, varscan2
- NUTM1 | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as rs529767971, COSV59215827, COSV59218697; called by muse, mutect2, varscan2
- OR51D1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 306/1010 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100712427; called by mutect2, varscan2
- OR9K2 | c.252G>T p.M84I (on ENST00000305377; = p.M62I on NM_001005243.1) | Missense Mutation (SNP) | VAF 422/902 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs568585391, COSV100543915; called by muse, mutect2, varscan2
- PDCL3 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 119/824 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200896946, COSV99959692; called by muse, varscan2
- PDE6C | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 100/1131 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs952628231, COSV101008850; called by muse, mutect2
- PRDM9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs112157044; called by muse, mutect2, varscan2
- PTPN3 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99356179; called by muse, mutect2, varscan2
- SLC12A5 | c.2408G>A p.R803H (on ENST00000454036 / NM_001134771.2; = p.R780H on NM_020708.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs779096129, COSV54793253; called by muse, mutect2, varscan2
- SLC25A13 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372216502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRF | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs767649010, COSV99335980; called by muse, mutect2, varscan2
- SSTR2 | c.242A>C p.Y81S | Missense Mutation (SNP) | VAF 394/642 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100192188; called by muse, varscan2
- STK24 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452699686, COSV64823209; called by muse, mutect2
- TEX37 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as rs754175306, COSV100304678; called by muse, mutect2, varscan2
- TMEFF2 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV99772322; called by muse, mutect2, varscan2
- TNC | c.2940C>G p.N980K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV60785763; called by mutect2, varscan2
- TRIM36 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV56690278, COSV99142606; called by muse, mutect2, varscan2
- TYR | c.967A>G p.S323G | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.253); catalogued as COSV99635197; called by muse, varscan2
- XDH | c.3750C>G p.N1250K | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV101052444; called by muse, mutect2, varscan2
- ZDHHC4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781761812, COSV60105939; called by muse, varscan2
- ZNF425 | c.1757A>T p.E586V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100955587; called by muse, mutect2
- BICD2 | c.1507_1509del p.E503del | In Frame Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- BPI | c.240del p.H81Ifs*19 (on ENST00000262865; = p.H77Ifs*19 on NM_001725.3) | Frame Shift Del (DEL) | VAF 32/187 reads (17%) | called by mutect2, pindel, varscan2
- FAM171B | c.482C>A p.S161* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- FCRL4 | c.831del p.Q278Rfs*63 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- ELAVL3 | c.861C>T p.F287= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs773924026, COSV52953523; called by mutect2, varscan2
- GPR149 | c.84G>A p.P28= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as rs373584683, COSV101078711; called by muse, mutect2, varscan2
- NID1 | c.780C>T p.V260= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99938231; called by muse, varscan2
- TBX21 | c.873C>A p.I291= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as rs1427729817, COSV99456279; called by muse, mutect2, varscan2
- TRA2B | c.774G>A p.Q258= | Silent (SNP) | VAF 42/752 reads (6%) | catalogued as COSV99373328; called by muse, mutect2
- TRPM3 | c.1029C>A p.P343= (on ENST00000357533 / NM_001366142.2; = p.P188= on NM_020952.6) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100677276; called by muse, varscan2
- ZNF16 | c.699G>A p.G233= | Silent (SNP) | VAF 22/171 reads (13%) | called by muse, varscan2
- ARPP19P1 | n.194A>G | RNA (SNP) | VAF 23/36 reads (64%) | catalogued as rs1391126276; called by muse, mutect2, varscan2
